Somatic mutation profile of tumor specimen 0DXXXX from CCDI case PBCRWU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Vipoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 15.2 years (5,546 days).
Specimen 0DXXXX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17e4eda5-ee49-44ee-9fc4-b241204475c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXXW9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39a6581f-b0f2-4934-8af6-f8023cd0f9a6

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIA4 | c.2080A>T p.T694S | Missense Mutation (SNP) | VAF 187/262 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR7A10 | c.456T>A p.S152R | Missense Mutation (SNP) | VAF 319/1215 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MICAL2 | c.4716C>T p.R1572= | Silent (SNP) | VAF 41/384 reads (11%) | called by muse, mutect2, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 24/840 reads (3%) | called by muse, mutect2
